Somatic mutation profile of tumor specimen C3N-01385-02 (aliquot CPT0162230034) from CPTAC case C3N-01385, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 66.8 years (24,392 days).
Specimen C3N-01385-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 142b0062-8c09-4a6f-a860-d46d4fb0b569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01385-31 (Blood Derived Normal), aliquot CPT0162290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae24fe3a-0bc8-4b70-8faa-39f5de354c5c

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2
- USP17L7 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773790291; called by muse, mutect2
- ZNF99 | c.2144G>C p.S715T | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs750728714, COSV68056033; called by muse, mutect2
- ANGPTL4 | c.764T>C p.F255S | Missense Mutation (SNP) | VAF 12/422 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2
- GAS2L3 | c.1900A>G p.T634A | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- MXRA8 | c.356A>T p.N119I | Missense Mutation (SNP) | VAF 11/340 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TIGAR | c.12C>T p.F4= | Silent (SNP) | VAF 8/246 reads (3%) | catalogued as rs1366407595, COSV99463857; called by muse, mutect2
